Somatic mutation profile of tumor specimen C3L-05517-01 (aliquot CPT0287530006) from CPTAC case C3L-05517, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 75.2 years (27,477 days).
Specimen C3L-05517-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Head & Neck; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f72b840-d931-4716-862b-3bfacf5b9277.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05517-32 (Blood Derived Normal), aliquot CPT0287520002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2dea7d3f-78e2-4a4a-b842-fdfa217d3135

The open-access MAF lists 278 somatic variants for this specimen: 184 protein-altering or splice-affecting, 84 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 164, Silent 84, Nonsense Mutation 14, Intron 8, Splice Region 4, 3'UTR 1, 3'Flank 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/253 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABLIM3 | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 95/306 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100448523; called by muse, mutect2, varscan2
- ADGRG4 | c.4096C>T p.P1366S | Missense Mutation (SNP) | VAF 151/503 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV54954152; called by muse, mutect2, varscan2
- ADH1A | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 120/322 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52924904; called by muse, mutect2, varscan2
- AKR1C3 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 67/190 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as COSV65910240; called by muse, mutect2, varscan2
- ARHGAP21 | c.2387C>T p.P796L | Missense Mutation (SNP) | VAF 85/257 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs138158463, COSV57609579; called by muse, mutect2, varscan2
- BUD13 | c.1693C>T p.R565C | Missense Mutation (SNP) | VAF 93/319 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.061); catalogued as rs772347423, COSV52767721; called by muse, mutect2, varscan2
- CALCR | c.1033G>A p.E345K (on ENST00000649521 / NM_001164737.2; = p.E329K on NM_001742.4) | Missense Mutation (SNP) | VAF 111/430 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.149); catalogued as rs1033749544, COSV64008265; called by muse, mutect2, varscan2
- CDC42BPG | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 98/322 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61349539; called by muse, varscan2
- CEACAM8 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 58/209 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as rs146875157, COSV54990636; called by muse, mutect2, varscan2
- CFAP54 | c.4993C>T p.P1665S | Missense Mutation (SNP) | VAF 75/311 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as COSV61571481; called by muse, mutect2, varscan2
- CFAP97 | c.899A>G p.N300S | Missense Mutation (SNP) | VAF 102/347 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as rs1213047469; called by muse, mutect2, varscan2
- CKAP5 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 74/229 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1459269840; called by muse, mutect2, varscan2
- CLASP2 | c.2715G>C p.Q905H | Missense Mutation (SNP) | VAF 63/218 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.072); catalogued as rs368363195; called by muse, mutect2, varscan2
- CNTN5 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 69/267 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.774); catalogued as rs1010130853, COSV54303038, COSV99676123; called by muse, mutect2, varscan2
- CRTC2 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 92/339 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.743); catalogued as rs531910512; called by muse, mutect2, varscan2
- CRYBA4 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 81/330 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1447609778; called by muse, mutect2, varscan2
- CXCR2 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 115/468 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1298311873, COSV59279763; called by muse, mutect2, varscan2
- DNAH8 | c.2893C>T p.P965S | Missense Mutation (SNP) | VAF 86/307 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV59477545; called by muse, mutect2, varscan2
- ELMO1 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 78/271 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs1352299028, COSV60312330; called by muse, mutect2, varscan2
- FAM155B | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 172/691 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as COSV52935495; called by muse, mutect2, varscan2
- FAM53C | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 166/533 reads (31%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.998); catalogued as COSV53511734; called by muse, mutect2, varscan2
- FAT3 | c.5176C>T p.Q1726* | Nonsense Mutation (SNP) | VAF 94/354 reads (27%) | catalogued as rs370831729; called by muse, mutect2, varscan2
- FAT3 | c.7171C>T p.P2391S | Missense Mutation (SNP) | VAF 85/340 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV53087943; called by muse, mutect2, varscan2
- FLG | c.12103G>A p.D4035N | Missense Mutation (SNP) | VAF 114/437 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV64239925; called by muse, mutect2, varscan2
- FLG | c.4148G>A p.R1383K | Missense Mutation (SNP) | VAF 166/698 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV100910512; called by muse, mutect2, varscan2
- FRMPD4 | c.347C>A p.P116Q | Missense Mutation (SNP) | VAF 104/400 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs748725184, COSV66217312; called by muse, mutect2, varscan2
- GPC5 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 134/402 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.333); catalogued as rs763165391, COSV65600430; called by muse, mutect2, varscan2
- GPR85 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 129/487 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.224); catalogued as COSV51784747; called by muse, mutect2, varscan2
- HS3ST4 | c.1342C>T p.Q448* | Nonsense Mutation (SNP) | VAF 108/339 reads (32%) | catalogued as rs1223869400, COSV58806602; called by muse, mutect2, varscan2
- IGLV1-44 | c.265A>T p.T89S | Missense Mutation (SNP) | VAF 126/520 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as rs572589957; called by muse, varscan2
- IL7R | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 61/298 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs866265601, COSV57410925; called by muse, mutect2, varscan2
- INSC | c.1592C>T p.A531V | Missense Mutation (SNP) | VAF 112/355 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as COSV65409816, COSV65409820; called by muse, mutect2, varscan2
- ITGA5 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 99/367 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53220130; called by muse, mutect2, varscan2
- KCNK16 | c.245A>G p.N82S | Missense Mutation (SNP) | VAF 119/380 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as COSV100949118; called by muse, mutect2, varscan2
- KIAA0100 | c.5867G>A p.G1956D | Missense Mutation (SNP) | VAF 88/353 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.776); catalogued as rs934448818; called by muse, mutect2, varscan2
- KIAA0319 | c.1357C>T p.L453F | Missense Mutation (SNP) | VAF 116/487 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as COSV100985457; called by muse, mutect2, varscan2
- KLHL14 | c.199C>A p.P67T | Missense Mutation (SNP) | VAF 257/806 reads (32%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.028); catalogued as rs765533940; called by muse, mutect2, varscan2
- KRT85 | c.1035G>A p.M345I | Missense Mutation (SNP) | VAF 120/461 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV57738431; called by muse, mutect2, varscan2
- LAMA5 | c.8243G>A p.R2748H | Missense Mutation (SNP) | VAF 113/414 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs749238842; called by muse, mutect2, varscan2
- LILRB2 | c.1283C>T p.P428L | Missense Mutation (SNP) | VAF 121/537 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as rs754413567; called by muse, mutect2, varscan2
- LOXHD1 | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 87/306 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs1283767907; called by muse, mutect2, varscan2
- LTF | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 90/333 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.132); catalogued as COSV51605639; called by muse, mutect2, varscan2
- LYPD5 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 81/302 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as rs773956808; called by muse, mutect2, varscan2
- MAGEC1 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 156/619 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as COSV53580455, COSV99596431; called by muse, mutect2, varscan2
- MAGEE2 | c.759G>A p.W253* | Nonsense Mutation (SNP) | VAF 135/530 reads (25%) | catalogued as rs866664899, COSV64898375; called by muse, mutect2, varscan2
- MAGEE2 | c.758G>A p.W253* | Nonsense Mutation (SNP) | VAF 134/532 reads (25%) | catalogued as rs1404130292; called by muse, mutect2, varscan2
- MINDY4B | c.1237A>G p.I413V | Missense Mutation (SNP) | VAF 69/156 reads (44%) | SIFT tolerated (0.84); PolyPhen benign (0.022); catalogued as rs1004259543; called by muse, mutect2, varscan2
- MKX | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 116/264 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV101008845; called by muse, mutect2, varscan2
- MORC4 | c.1727G>A p.R576Q | Missense Mutation (SNP) | VAF 123/434 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV55239939; called by muse, mutect2, varscan2
- MUC16 | c.16375C>A p.L5459M | Missense Mutation (SNP) | VAF 71/502 reads (14%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.003); catalogued as COSV67448443; called by muse, mutect2, varscan2
- MXRA5 | c.6650G>A p.G2217E | Missense Mutation (SNP) | VAF 160/550 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54229091; called by muse, mutect2, varscan2
- NAALAD2 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 83/240 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1322204773, COSV58958338; called by muse, mutect2, varscan2
- NCAM1 | c.1546G>A p.D516N (on ENST00000316851 / NM_181351.5; = p.D506N on NM_000615.7) | Missense Mutation (SNP) | VAF 103/380 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.105); catalogued as rs1027853289; called by muse, mutect2, varscan2
- NCKAP5 | c.2566C>T p.L856F | Missense Mutation (SNP) | VAF 84/361 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.018); catalogued as rs1021392247; called by muse, mutect2, varscan2
- NEXMIF | c.3484C>T p.P1162S | Missense Mutation (SNP) | VAF 141/549 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.187); catalogued as COSV50043218; called by muse, mutect2, varscan2
- NOXA1 | c.1261C>T p.R421* | Nonsense Mutation (SNP) | VAF 83/287 reads (29%) | catalogued as rs113228211; called by muse, mutect2, varscan2
- NTPCR | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 120/430 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV64052341; called by muse, mutect2, varscan2
- OR10A3 | c.161G>A p.S54N | Missense Mutation (SNP) | VAF 168/571 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs753474515, COSV62459816; called by muse, mutect2, varscan2
- OR2T1 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 184/693 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100822237, COSV63541456; called by muse, mutect2, varscan2
- OR2Y1 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 157/504 reads (31%) | catalogued as rs777536452; called by muse, mutect2, varscan2
- PCDH12 | c.3301A>G p.T1101A | Missense Mutation (SNP) | VAF 184/609 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs144910513; called by muse, mutect2, varscan2
- PDE1C | c.342G>A p.M114I | Missense Mutation (SNP) | VAF 142/512 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.765); catalogued as rs757845854; called by muse, mutect2, varscan2
- PER1 | c.1417C>T p.P473S | Missense Mutation (SNP) | VAF 137/473 reads (29%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.986); catalogued as COSV100424672; called by muse, mutect2, varscan2
- PIK3C2G | c.2335C>T p.R779C (on ENST00000676171; = p.R738C on NM_004570.5) | Missense Mutation (SNP) | VAF 71/289 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759658584, COSV56799291; called by muse, mutect2, varscan2
- PPFIA2 | c.754C>T p.H252Y | Missense Mutation (SNP) | VAF 70/290 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as rs866763827, COSV61044230; called by muse, mutect2, varscan2
- PREX2 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 237/426 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753863699, COSV55794786; called by muse, mutect2, varscan2
- RGPD3 | c.2851G>A p.D951N | Missense Mutation (SNP) | VAF 132/605 reads (22%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.468); catalogued as rs753658071; called by muse, mutect2, varscan2
- RHOB | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 139/455 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.506); catalogued as COSV55355269, COSV55355916; called by muse, mutect2, varscan2
- RHOXF2 | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 133/1015 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs781804581, COSV65047776; called by muse, mutect2, varscan2
- RP1 | c.4219G>A p.E1407K | Missense Mutation (SNP) | VAF 187/323 reads (58%) | SIFT tolerated (0.53); PolyPhen benign (0.203); catalogued as COSV55114666; called by muse, mutect2, varscan2
- RXFP1 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 93/313 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV57047602, COSV57049764; called by muse, mutect2, varscan2
- SALL3 | c.2621G>A p.R874H | Missense Mutation (SNP) | VAF 206/683 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV73305920; called by muse, mutect2, varscan2
- SH2B1 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 174/571 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV59467819; called by muse, mutect2, varscan2
- SH3RF1 | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 121/409 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.257); catalogued as rs762293008; called by muse, mutect2, varscan2
- SLC22A24 | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 104/319 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762131136; called by muse, mutect2, varscan2
- SLC30A7 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 69/263 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63017633; called by muse, mutect2, varscan2
- SLC39A10 | c.1772C>T p.S591F | Missense Mutation (SNP) | VAF 82/335 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs376861733, COSV62769653; called by muse, mutect2, varscan2
- SLC8A1 | c.2287G>A p.D763N | Missense Mutation (SNP) | VAF 73/316 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.177); catalogued as rs760569632, COSV60472601; called by muse, mutect2, varscan2
- SLFN12L | c.458G>A p.G153E (on ENST00000260908 / NM_001363830.1; = p.G171E on NM_001195790.1) | Missense Mutation (SNP) | VAF 113/501 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as rs774713158; called by muse, mutect2, varscan2
- SOX10 | c.524C>A p.P175H | Missense Mutation (SNP) | VAF 24/780 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM119676, CM119679, COSV62806811; called by muse, mutect2
- STXBP5L | c.1359G>A p.W453* | Nonsense Mutation (SNP) | VAF 92/228 reads (40%) | catalogued as COSV56525818; called by muse, mutect2, varscan2
- SURF2 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 111/290 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.231); catalogued as rs111352323; called by muse, mutect2, varscan2
- TMEM132C | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 128/413 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.7); catalogued as COSV59429272; called by muse, mutect2, varscan2
- TNK2 | c.2221C>T p.P741S | Missense Mutation (SNP) | VAF 171/376 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.357); catalogued as COSV100361533; called by muse, mutect2, varscan2
- TRABD | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 187/585 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100326955; called by muse, mutect2, varscan2
- TTN | c.12739G>A p.E4247K (on ENST00000591111; = p.E4201K on NM_003319.4) | Missense Mutation (SNP) | VAF 140/428 reads (33%) | catalogued as rs746672079, COSV60169973; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBAP2L | c.2995C>T p.H999Y | Missense Mutation (SNP) | VAF 99/340 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55170884; called by muse, mutect2, varscan2
- WDFY3 | c.6821C>T p.S2274F | Missense Mutation (SNP) | VAF 131/505 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as COSV55692131; called by muse, mutect2, varscan2
- WDR64 | c.1127A>G p.E376G | Missense Mutation (SNP) | VAF 109/399 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as rs756917112; called by muse, mutect2, varscan2
- WIPF3 | c.100G>T p.D34Y | Missense Mutation (SNP) | VAF 120/349 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV99635200; called by muse, mutect2, varscan2
- WSCD2 | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 83/307 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54583790; called by muse, mutect2, varscan2
- ZNF621 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 89/399 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV59458026; called by muse, mutect2, varscan2
- ABCC8 | c.2818A>G p.K940E | Missense Mutation (SNP) | VAF 54/216 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.012); called by muse, mutect2
- AC025287.4 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 98/340 reads (29%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- ADAD1 | c.1017G>A p.Q339= | Splice Region (SNP) | VAF 46/203 reads (23%) | called by muse, mutect2, varscan2
- ADAM8 | c.1586C>T p.S529F | Missense Mutation (SNP) | VAF 144/364 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- ADAMTS6 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 91/321 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADGRG4 | c.5413A>T p.T1805S | Missense Mutation (SNP) | VAF 162/572 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2
- ANKRD35 | c.2087C>T p.S696F | Missense Mutation (SNP) | VAF 141/453 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- API5 | c.247A>G p.I83V | Missense Mutation (SNP) | VAF 78/339 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- APOB | c.8792G>A p.W2931* | Nonsense Mutation (SNP) | VAF 127/520 reads (24%) | called by muse, mutect2, varscan2
- BATF | c.130C>G p.R44G | Missense Mutation (SNP) | VAF 137/410 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- BTBD8 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 63/213 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C8orf74 | c.274G>A p.G92R | Missense Mutation (SNP) | VAF 92/245 reads (38%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- CCDC144A | c.4099-1G>A p.X1367_splice | Splice Site (SNP) | VAF 26/293 reads (9%) | called by muse, mutect2, varscan2
- CDR1 | c.554G>A p.W185* | Nonsense Mutation (SNP) | VAF 162/645 reads (25%) | called by muse, mutect2, varscan2
- CLIP2 | c.2648C>T p.T883I | Missense Mutation (SNP) | VAF 153/583 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CNST | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 96/368 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL5A3 | c.3130G>A p.E1044K | Missense Mutation (SNP) | VAF 92/419 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- CRB1 | c.2597C>T p.P866L | Missense Mutation (SNP) | VAF 85/354 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- CTAGE9 | c.2119C>T p.P707S | Missense Mutation (SNP) | VAF 165/438 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- CYP26B1 | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 225/644 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CYSLTR1 | c.702G>A p.M234I | Missense Mutation (SNP) | VAF 147/548 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- DBH | c.893T>G p.V298G | Missense Mutation (SNP) | VAF 107/255 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by mutect2, varscan2
- DLGAP2 | c.2153G>A p.G718E | Missense Mutation (SNP) | VAF 108/240 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DSG4 | c.1003A>G p.K335E | Missense Mutation (SNP) | VAF 92/280 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- DSG4 | c.1005G>A p.K335= | Splice Region (SNP) | VAF 88/274 reads (32%) | called by muse, mutect2
- DTD1 | c.311G>A p.G104D | Missense Mutation (SNP) | VAF 89/415 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- EFHB | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 77/194 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EPOP | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 182/690 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAM149A | c.2219A>T p.H740L (on ENST00000356371 / NM_001367768.2; = p.H449L on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 89/325 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FBXW9 | c.703G>A p.D235N (on ENST00000587955; = p.D245N on NM_032301.3) | Missense Mutation (SNP) | VAF 110/418 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FHOD1 | c.1214C>T p.S405F | Missense Mutation (SNP) | VAF 189/675 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOXD3 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 137/509 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- GDI1 | c.470C>T p.T157I | Missense Mutation (SNP) | VAF 173/587 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- GOLGA6C | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 84/509 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, varscan2
- HSF5 | c.881A>C p.N294T | Missense Mutation (SNP) | VAF 122/405 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- HTATSF1 | c.2206G>T p.G736W | Missense Mutation (SNP) | VAF 182/668 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- HYDIN | c.14099A>G p.N4700S | Missense Mutation (SNP) | VAF 74/317 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IL1R2 | c.602A>G p.D201G | Missense Mutation (SNP) | VAF 80/336 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IQUB | c.737C>T p.S246F | Missense Mutation (SNP) | VAF 97/368 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- IRX2 | c.448C>G p.L150V | Missense Mutation (SNP) | VAF 190/729 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNJ3 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 98/266 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KIF21A | c.4588G>T p.G1530W (on ENST00000361418 / NM_001378440.1; = p.G1517W on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/382 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- KLF5 | c.1197T>G p.G399= | Splice Region (SNP) | VAF 89/325 reads (27%) | called by muse, mutect2, varscan2
- LGR5 | c.1893G>A p.W631* | Nonsense Mutation (SNP) | VAF 119/376 reads (32%) | called by muse, mutect2, varscan2
- MAGEA11 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 161/541 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- MEST | c.436C>T p.H146Y | Missense Mutation (SNP) | VAF 119/441 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- MTMR11 | c.899T>C p.V300A (on ENST00000439741 / NM_001145862.2; = p.V228A on NM_181873.3) | Missense Mutation (SNP) | VAF 120/410 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- MYH3 | c.2585A>T p.D862V | Missense Mutation (SNP) | VAF 134/477 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYH8 | c.2061G>A p.M687I | Missense Mutation (SNP) | VAF 73/302 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- MYT1L | c.3400C>T p.Q1134* | Nonsense Mutation (SNP) | VAF 101/454 reads (22%) | called by muse, mutect2, varscan2
- NCBP2L | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 111/375 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- NEMF | c.128A>G p.K43R | Missense Mutation (SNP) | VAF 67/223 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- NOTCH4 | c.2767C>T p.Q923* | Nonsense Mutation (SNP) | VAF 210/972 reads (22%) | called by muse, mutect2, varscan2
- NPAT | c.2491G>A p.D831N | Missense Mutation (SNP) | VAF 138/468 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- NSD1 | c.3254C>T p.P1085L | Missense Mutation (SNP) | VAF 116/400 reads (29%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NXPH1 | c.503T>G p.V168G | Missense Mutation (SNP) | VAF 156/563 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- OBSCN | c.15116C>T p.P5039L | Missense Mutation (SNP) | VAF 121/503 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR8B4 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 114/432 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PAPPA | c.1627G>T p.G543C | Missense Mutation (SNP) | VAF 80/181 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PASD1 | c.1673C>T p.P558L | Missense Mutation (SNP) | VAF 179/613 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDH15 | c.847C>T p.Q283* | Nonsense Mutation (SNP) | VAF 89/256 reads (35%) | called by muse, mutect2, varscan2
- PCDHB3 | c.2237C>T p.S746F | Missense Mutation (SNP) | VAF 86/456 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PCSK5 | c.173G>A p.G58E | Missense Mutation (SNP) | VAF 99/231 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PCSK6 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 85/339 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PRR12 | c.2009C>T p.P670L (on ENST00000615927; = p.P1491L on NM_020719.3) | Missense Mutation (SNP) | VAF 136/522 reads (26%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PTPRM | c.3898C>T p.P1300S | Missense Mutation (SNP) | VAF 80/314 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- RFC1 | c.1460C>T p.S487F | Missense Mutation (SNP) | VAF 107/349 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- RFX2 | c.998A>T p.H333L | Missense Mutation (SNP) | VAF 90/369 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- RIMS1 | c.3007C>T p.H1003Y | Missense Mutation (SNP) | VAF 77/293 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- RP1 | c.3810G>A p.M1270I | Missense Mutation (SNP) | VAF 90/292 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SIMC1 | c.212C>T p.S71F (on ENST00000443967 / NM_001308196.1; = p.S90F on NM_001308195.2) | Missense Mutation (SNP) | VAF 157/480 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- SLF1 | c.1830C>T p.V610= | Splice Region (SNP) | VAF 64/248 reads (26%) | called by muse, mutect2, varscan2
- SSH3 | c.1271T>C p.V424A | Missense Mutation (SNP) | VAF 160/539 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SSU72P5 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 77/450 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TAS2R19 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 158/543 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- TCEAL2 | c.613A>G p.R205G | Missense Mutation (SNP) | VAF 178/492 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TCERG1L | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 82/238 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- TCP11X2 | c.725C>T p.T242I | Missense Mutation (SNP) | VAF 108/575 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2
- TLR8 | c.1510C>A p.L504I (on ENST00000218032 / NM_138636.5; = p.L522I on NM_016610.4) | Missense Mutation (SNP) | VAF 31/436 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.084); called by muse, mutect2
- TM7SF3 | c.29_30insAC p.V11Rfs*53 | Frame Shift Ins (INS) | VAF 92/410 reads (22%) | called by mutect2, pindel, varscan2
- TNRC6A | c.3028G>A p.D1010N | Missense Mutation (SNP) | VAF 100/402 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TOX3 | c.1579C>T p.Q527* | Nonsense Mutation (SNP) | VAF 112/437 reads (26%) | called by muse, mutect2, varscan2
- TRAV20 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 83/302 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- TTI1 | c.529T>G p.C177G | Missense Mutation (SNP) | VAF 124/468 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- UNC13C | c.3688C>A p.Q1230K | Missense Mutation (SNP) | VAF 64/285 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- USP32 | c.2836T>C p.Y946H | Missense Mutation (SNP) | VAF 95/319 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZNF182 | c.1501C>T p.L501F | Missense Mutation (SNP) | VAF 129/463 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- ZNF229 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 86/333 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZNF318 | c.4187C>T p.S1396L | Missense Mutation (SNP) | VAF 121/498 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- ZNF621 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 92/402 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- ZNF99 | c.2162G>A p.R721K | Missense Mutation (SNP) | VAF 141/508 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- AFAP1 | c.1450C>T p.L484= | Silent (SNP) | VAF 117/361 reads (32%) | catalogued as rs1435756370; called by muse, mutect2, varscan2
- AMY1A | c.921G>A p.A307= | Silent (SNP) | VAF 79/406 reads (19%) | catalogued as rs374810253; called by muse, mutect2, varscan2
- ANK1 | c.5448G>A p.T1816= | Silent (SNP) | VAF 120/294 reads (41%) | catalogued as rs146637140; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BPIFB3 | c.636C>T p.L212= | Silent (SNP) | VAF 109/390 reads (28%) | catalogued as rs752000596; called by muse, mutect2, varscan2
- BTBD17 | c.1383C>T p.H461= | Silent (SNP) | VAF 168/529 reads (32%) | catalogued as rs1201057705; called by muse, mutect2, varscan2
- BTNL2 | c.717C>G p.L239= | Silent (SNP) | VAF 80/410 reads (20%) | called by muse, mutect2, varscan2
- C4A | c.4098C>A p.I1366= | Silent (SNP) | VAF 56/496 reads (11%) | called by muse, mutect2, varscan2
- C7orf26 | c.1203C>T p.L401= | Silent (SNP) | VAF 148/521 reads (28%) | catalogued as rs1562563291, COSV60418577; called by muse, mutect2, varscan2
- CACNG5 | c.558C>T p.F186= | Silent (SNP) | VAF 93/271 reads (34%) | catalogued as COSV50058885; called by muse, mutect2, varscan2
- CDK20 | c.876C>T p.P292= (on ENST00000325303 / NM_001039803.3; = p.P271= on NM_012119.4) | Silent (SNP) | VAF 136/333 reads (41%) | called by muse, mutect2, varscan2
- CEP120 | c.60C>T p.F20= | Silent (SNP) | VAF 63/232 reads (27%) | called by muse, mutect2, varscan2
- CHST1 | c.450G>A p.R150= | Silent (SNP) | VAF 147/555 reads (26%) | called by muse, mutect2, varscan2
- COL6A1 | c.1494C>T p.P498= | Silent (SNP) | VAF 120/434 reads (28%) | called by muse, mutect2, varscan2
- COPA | c.2269C>T p.L757= | Silent (SNP) | VAF 67/300 reads (22%) | called by muse, mutect2, varscan2
- COPA | c.2268C>T p.S756= | Silent (SNP) | VAF 68/296 reads (23%) | called by muse, mutect2, varscan2
- DCN | c.447C>T p.P149= | Silent (SNP) | VAF 112/292 reads (38%) | catalogued as rs915287751, COSV50007789; called by muse, mutect2, varscan2
- DNAH10 | c.2175C>T p.I725= (on ENST00000409039; = p.I664= on NM_207437.3) | Silent (SNP) | VAF 102/387 reads (26%) | called by muse, mutect2, varscan2
- DNAH17 | c.7968C>T p.L2656= | Silent (SNP) | VAF 123/432 reads (28%) | called by muse, mutect2, varscan2
- DNAJC30 | c.49T>C p.L17= | Silent (SNP) | VAF 129/455 reads (28%) | called by muse, mutect2, varscan2
- DUSP22 | c.168G>A p.A56= | Silent (SNP) | VAF 52/501 reads (10%) | catalogued as rs372273804, COSV60530759; called by muse, mutect2, varscan2
- F11R | c.882C>T p.T294= | Silent (SNP) | VAF 104/395 reads (26%) | called by muse, mutect2, varscan2
- FAM53C | c.327C>T p.P109= | Silent (SNP) | VAF 166/535 reads (31%) | called by muse, mutect2, varscan2
- FBXL15 | c.24C>T p.S8= | Silent (SNP) | VAF 108/269 reads (40%) | catalogued as rs145475543; called by muse, mutect2, varscan2
- FBXO33 | c.577C>T p.L193= | Silent (SNP) | VAF 76/272 reads (28%) | catalogued as rs957881830; called by muse, varscan2
- FCER1A | c.736C>T p.L246= | Silent (SNP) | VAF 92/340 reads (27%) | called by muse, mutect2, varscan2
- GABRR2 | c.1266G>A p.K422= | Silent (SNP) | VAF 159/609 reads (26%) | called by muse, mutect2, varscan2
- GBP6 | c.282C>T p.V94= | Silent (SNP) | VAF 72/300 reads (24%) | called by muse, mutect2, varscan2
- GLI2 | c.2709G>A p.L903= (on ENST00000361492 / NM_001374353.1; = p.L920= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 145/499 reads (29%) | called by muse, mutect2, varscan2
- GNPTAB | c.1992C>T p.I664= | Silent (SNP) | VAF 112/426 reads (26%) | catalogued as rs778140756; called by muse, mutect2, varscan2
- GPR1 | c.273C>T p.P91= | Silent (SNP) | VAF 130/441 reads (29%) | called by muse, mutect2, varscan2
- GRIN2A | c.3594C>T p.S1198= | Silent (SNP) | VAF 144/498 reads (29%) | called by muse, mutect2, varscan2
- HCN1 | c.2079C>T p.I693= | Silent (SNP) | VAF 157/499 reads (31%) | called by muse, mutect2, varscan2
- HECA | c.1251T>G p.T417= | Silent (SNP) | VAF 129/331 reads (39%) | called by muse, mutect2, varscan2
- IGLV1-44 | c.264C>G p.G88= | Silent (SNP) | VAF 126/522 reads (24%) | catalogued as rs1286875323; called by muse, varscan2
- IGLV2-11 | c.90C>T p.S30= | Silent (SNP) | VAF 128/460 reads (28%) | catalogued as rs551962962; called by muse, mutect2, varscan2
- IGLV4-3 | c.186C>T p.S62= | Silent (SNP) | VAF 73/322 reads (23%) | called by muse, mutect2, varscan2
- KCNK1 | c.591C>T p.F197= | Silent (SNP) | VAF 124/584 reads (21%) | catalogued as COSV64035105; called by muse, mutect2, varscan2
- LBR | c.909C>T p.I303= | Silent (SNP) | VAF 52/230 reads (23%) | called by muse, mutect2
- LGI2 | c.1101G>A p.L367= | Silent (SNP) | VAF 120/497 reads (24%) | called by muse, mutect2, varscan2
- LRRC53 | c.453C>T p.F151= | Silent (SNP) | VAF 57/271 reads (21%) | called by muse, mutect2, varscan2
- ME3 | c.504T>G p.L168= | Silent (SNP) | VAF 111/405 reads (27%) | called by muse, mutect2, varscan2
- MRGPRX1 | c.621G>A p.R207= | Silent (SNP) | VAF 153/568 reads (27%) | catalogued as COSV100245895; called by muse, mutect2, varscan2
- MUC12 | c.6492C>T p.F2164= (on ENST00000379442; = p.F2021= on NM_001164462.1) | Silent (SNP) | VAF 174/1786 reads (10%) | called by muse, mutect2, varscan2
- MUC16 | c.23712C>T p.T7904= | Silent (SNP) | VAF 142/526 reads (27%) | called by muse, mutect2, varscan2
- MYH8 | c.5106G>A p.R1702= | Silent (SNP) | VAF 116/462 reads (25%) | catalogued as rs140525529, COSV67965310; called by muse, mutect2, varscan2
- MYO7A | c.2847C>T p.F949= | Silent (SNP) | VAF 119/447 reads (27%) | catalogued as rs1555084293; ClinVar: likely benign; called by muse, mutect2, varscan2
- NOXA1 | c.1260C>T p.F420= | Silent (SNP) | VAF 83/290 reads (29%) | catalogued as rs1306129515; called by muse, mutect2, varscan2
- OGDHL | c.513G>A p.K171= | Silent (SNP) | VAF 84/212 reads (40%) | catalogued as rs1338005301; called by muse, mutect2, varscan2
- OR13G1 | c.27C>T p.F9= | Silent (SNP) | VAF 90/334 reads (27%) | catalogued as rs760889320, COSV100687173; called by muse, mutect2, varscan2
- OR4K5 | c.897G>A p.R299= | Silent (SNP) | VAF 67/228 reads (29%) | catalogued as rs749816085, COSV60003526; called by muse, mutect2, varscan2
- OR56B4 | c.54C>T p.F18= | Silent (SNP) | VAF 112/417 reads (27%) | catalogued as rs374452817; called by muse, mutect2, varscan2
- OR5L2 | c.600C>T p.F200= | Silent (SNP) | VAF 102/376 reads (27%) | catalogued as rs185746996, COSV65723999, COSV65724294; called by muse, mutect2, varscan2
- PCDHB16 | c.2214C>T p.D738= | Silent (SNP) | VAF 141/513 reads (27%) | catalogued as rs782670208, COSV53361340; called by muse, mutect2, varscan2
- PCDHGA6 | c.2091G>T p.V697= | Silent (SNP) | VAF 175/666 reads (26%) | called by muse, mutect2, varscan2
- PCOLCE | c.55C>T p.L19= | Silent (SNP) | VAF 169/533 reads (32%) | catalogued as rs1479666472; called by muse, mutect2, varscan2
- PCSK7 | c.91C>T p.L31= | Silent (SNP) | VAF 187/581 reads (32%) | catalogued as COSV56118493; called by muse, mutect2, varscan2
- PER2 | c.3153C>T p.S1051= | Silent (SNP) | VAF 119/412 reads (29%) | catalogued as rs760163001; called by muse, mutect2, varscan2
- PPP1R2B | c.102G>A p.R34= | Silent (SNP) | VAF 114/394 reads (29%) | called by muse, mutect2, varscan2
- PRAMEF10 | c.1035G>A p.E345= | Silent (SNP) | VAF 83/698 reads (12%) | called by muse, varscan2
- PRAMEF2 | c.1107C>T p.I369= | Silent (SNP) | VAF 141/499 reads (28%) | catalogued as COSV53577030, COSV53579380; called by muse, mutect2, varscan2
- PRAMEF6 | c.1245C>T p.A415= | Silent (SNP) | VAF 178/937 reads (19%) | catalogued as rs552909609; called by muse, mutect2
- PRPF8 | c.3726C>T p.N1242= | Silent (SNP) | VAF 162/532 reads (30%) | called by muse, mutect2, varscan2
- RBP3 | c.1432C>T p.L478= | Silent (SNP) | VAF 143/388 reads (37%) | called by muse, mutect2, varscan2
- REELD1 | c.823C>T p.L275= | Silent (SNP) | VAF 115/378 reads (30%) | catalogued as rs1163908075; called by muse, mutect2, varscan2
- RTL9 | c.195G>A p.L65= | Silent (SNP) | VAF 115/372 reads (31%) | called by muse, mutect2, varscan2
- SELP | c.2415G>A p.G805= | Silent (SNP) | VAF 50/201 reads (25%) | called by muse, mutect2, varscan2
- SIGLEC10 | c.288C>A p.P96= | Silent (SNP) | VAF 146/473 reads (31%) | called by muse, mutect2, varscan2
- SIGLEC8 | c.846C>T p.V282= | Silent (SNP) | VAF 161/501 reads (32%) | called by muse, mutect2, varscan2
- SLC26A6 | c.1722C>T p.S574= | Silent (SNP) | VAF 90/340 reads (26%) | catalogued as rs772152021; called by muse, mutect2, varscan2
- SLC9B1 | c.1398G>A p.A466= | Silent (SNP) | VAF 63/651 reads (10%) | catalogued as rs776033150, COSV99599642; called by muse, mutect2, varscan2
- SLIT2 | c.3456G>A p.Q1152= | Silent (SNP) | VAF 89/293 reads (30%) | called by muse, mutect2, varscan2
- SLIT3 | c.3612G>A p.L1204= | Silent (SNP) | VAF 122/421 reads (29%) | called by muse, mutect2, varscan2
- SPTB | c.2058C>T p.L686= | Silent (SNP) | VAF 152/501 reads (30%) | catalogued as COSV101072228; called by muse, mutect2, varscan2
- TCAF2 | c.661C>T p.L221= | Silent (SNP) | VAF 34/242 reads (14%) | called by muse, mutect2, varscan2
- TDRD5 | c.2142G>A p.E714= | Silent (SNP) | VAF 92/256 reads (36%) | called by muse, mutect2
- THSD7B | c.1065G>A p.G355= | Silent (SNP) | VAF 127/402 reads (32%) | catalogued as COSV55688829; called by muse, mutect2, varscan2
- TNS2 | c.3921C>T p.P1307= (on ENST00000314250 / NM_170754.4; = p.P1317= on NM_015319.2) | Silent (SNP) | VAF 144/537 reads (27%) | called by muse, mutect2, varscan2
- TRPM1 | c.255C>T p.L85= | Silent (SNP) | VAF 128/506 reads (25%) | called by muse, mutect2, varscan2
- TTN | c.90621G>A p.E30207= (on ENST00000591111; = p.E22783= on NM_003319.4) | Silent (SNP) | VAF 122/400 reads (31%) | catalogued as rs780704803; called by muse, mutect2, varscan2
- UNC13A | c.1323G>A p.Q441= | Silent (SNP) | VAF 117/478 reads (24%) | catalogued as rs372645121; called by muse, mutect2, varscan2
- ZBED9 | c.762G>A p.K254= | Silent (SNP) | VAF 98/523 reads (19%) | catalogued as rs765875050; called by muse, mutect2, varscan2
- ZNF226 | c.954G>A p.Q318= | Silent (SNP) | VAF 22/528 reads (4%) | called by muse, mutect2
- ZNF335 | c.990C>T p.P330= | Silent (SNP) | VAF 151/496 reads (30%) | called by muse, mutect2, varscan2
- ZNF556 | c.1350G>A p.K450= | Silent (SNP) | VAF 73/243 reads (30%) | catalogued as rs267605400, COSV100298679; called by muse, mutect2, varscan2
- AC093512.2 | c.306+3649C>T | Intron (SNP) | VAF 107/381 reads (28%) | called by muse, mutect2, varscan2
- ARHGEF28 | c.4948+11550C>T | Intron (SNP) | VAF 104/383 reads (27%) | catalogued as rs1397052908; called by muse, mutect2, varscan2
- GRM5 | c.661+62374T>C | Intron (SNP) | VAF 92/309 reads (30%) | called by muse, mutect2, varscan2
- KCNC1 | chr11:17779466 G>A | 3'Flank (SNP) | VAF 92/312 reads (29%) | called by muse, mutect2, varscan2
- MEF2B | c.769+224C>T | Intron (SNP) | VAF 87/280 reads (31%) | called by muse, mutect2, varscan2
- NEDD4L | c.49-16247A>T | Intron (SNP) | VAF 94/363 reads (26%) | called by muse, mutect2, varscan2
- SPRR2B | c.*287G>A | 3'UTR (SNP) | VAF 122/465 reads (26%) | catalogued as COSV100482265; called by muse, mutect2, varscan2
- TCAF2 | c.2505+29G>A | Intron (SNP) | VAF 48/139 reads (35%) | catalogued as COSV100633720; called by muse, mutect2, varscan2
- ZNF160 | c.271+728C>T | Intron (SNP) | VAF 149/552 reads (27%) | called by muse, mutect2, varscan2
- ZNF451 | c.186+2070G>A | Intron (SNP) | VAF 105/405 reads (26%) | called by muse, mutect2, varscan2
